HCMI case HCM-BROD-0870-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/325efd72-eaf4-4e85-80d0-911d360434d1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1960; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 50.3 years (18,388 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: T3b; AJCC pathologic N: N3; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Treatment intent type: Neoadjuvant; Days to treatment start: 818 days (2.2 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 3,669 days (10.0 years); Days to treatment end: 3,752 days (10.3 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 3,669 days (10.0 years); Days to treatment end: 3,752 days (10.3 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; neoadjuvant Radiation Therapy, NOS.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.8; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 59.9 years (21,864 days); Days to diagnosis: 3,476 days (9.5 years); Satellite nodule present: Indeterminate.
   Pathology details: Breslow thickness category: >2.0-4.0 mm; Lymph nodes positive: 3; Lymph nodes tested: 15.

Follow-up (2 entries)
- Days to follow up: 3,764 days (10.3 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 3,603.

Molecular and laboratory tests
- BRAF mutation, nos: Positive; Amino-acid change: V600E.
- KIT mutation, nos: Negative.
- NRAS mutation, nos: Negative.
- TP53 mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 106 kg; Height: 169 cm; BMI: 39.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0870-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0870-C43-06B-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0870-C43-06B-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0870-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0870-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 12.
